Somatic mutation profile of tumor specimen ALCH-B4Q6-TTP1-A (aliquot ALCH-B4Q6-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4Q6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.1 years (28,541 days).
Specimen ALCH-B4Q6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bdbebaf-286f-46c1-a098-20a4c318e377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4Q6-NB1-A (Blood Derived Normal), aliquot ALCH-B4Q6-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/466e3ef1-5a78-458a-985e-70a5004dbc61

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 3'UTR 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 65/738 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- F13A1 | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606787, CM093521, COSV53565534; ClinVar: pathogenic; called by muse, mutect2
- PCDHA11 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 18/616 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV56501614; called by muse, mutect2
- STS | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV54270785; called by muse, mutect2, varscan2
- ABCA13 | c.8047C>T p.P2683S | Missense Mutation (SNP) | VAF 15/505 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ADRB2 | c.1019T>A p.L340Q | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DDX24 | c.962C>A p.T321N | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.272); called by muse, mutect2
- EGFR | c.2102A>T p.Q701L | Missense Mutation (SNP) | VAF 75/695 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GGT7 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- KCND3 | c.1106+2T>A p.X369_splice | Splice Site (SNP) | VAF 15/387 reads (4%) | called by muse, mutect2
- MPL | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 18/332 reads (5%) | called by muse, mutect2
- OVCH2 | c.420C>A p.D140E | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.073); called by muse, mutect2
- SATB1 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 29/616 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.225); called by muse, mutect2
- ZNF813 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- CCDC182 | c.234C>T p.D78= | Silent (SNP) | VAF 18/229 reads (8%) | catalogued as rs369504693, COSV54989293; called by muse, mutect2
- FAM71C | c.186G>A p.V62= | Silent (SNP) | VAF 10/290 reads (3%) | catalogued as COSV100175655; called by muse, mutect2
- PRPF8 | c.960C>T p.Y320= | Silent (SNP) | VAF 38/654 reads (6%) | catalogued as rs750662375; called by muse, mutect2
- SENP3 | c.741C>T p.N247= | Silent (SNP) | VAF 26/235 reads (11%) | catalogued as rs757683945; called by muse, mutect2, varscan2
- CASC3 | c.*26T>A | 3'UTR (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- IL36RN | c.*26G>C | 3'UTR (SNP) | VAF 14/361 reads (4%) | catalogued as COSV100697247; called by muse, mutect2
